Somatic mutation profile of tumor specimen TCGA-B5-A0K8-01A (aliquot TCGA-B5-A0K8-01A-11D-A14K-09) from TCGA case TCGA-B5-A0K8, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 71.2 years (25,992 days).
Specimen TCGA-B5-A0K8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 63ce276f-fd68-4973-a5f7-65fcc6701276.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B5-A0K8-10B (Blood Derived Normal), aliquot TCGA-B5-A0K8-10B-01D-A14K-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/874493ef-4e48-4250-a4c8-d64548ce031d

The open-access MAF lists 51 somatic variants for this specimen: 35 protein-altering or splice-affecting, 16 silent.
By variant classification: Missense Mutation 32, Silent 16, Nonsense Mutation 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FRAS1 | c.4271C>G p.S1424* | Nonsense Mutation (SNP) | VAF 4/36 reads (11%) | catalogued as rs120074159, CM031180, COSV53633021; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 10/15 reads (67%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as rs28934874, CM012662, CM120847, CM941326, COSV52661698, COSV52676321, COSV52676982, COSV52701855; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.2413G>A p.D805N | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV55951709, COSV55958888; called by muse, mutect2
- C4orf33 | c.83G>A p.R28K | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV55416604; called by muse, mutect2, varscan2
- CACNB1 | c.1793G>A p.R598H | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs781076028, COSV59999714; called by muse, mutect2, varscan2
- CATSPER4 | c.605G>A p.R202Q | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.976); catalogued as rs768987248, COSV58794089; called by muse, mutect2, varscan2
- CDH23 | c.6511C>T p.R2171C | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs781698111, CD084050, CM078753, COSV56480429; called by muse, mutect2, varscan2
- CLDN9 | c.275T>A p.L92Q | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV60911381; called by muse, mutect2, varscan2
- CLEC18A | c.1225G>A p.V409M | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1431509593, COSV55344522; called by muse, varscan2
- COL27A1 | c.787G>A p.D263N | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs200344636, COSV61929456; called by muse, mutect2, varscan2
- COLEC10 | c.116G>A p.C39Y | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV60522464; called by muse, mutect2, varscan2
- DMTF1 | c.1793C>T p.S598F | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); catalogued as COSV57539095; called by muse, mutect2, varscan2
- GLT6D1 | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs200843676, COSV65628200; called by muse, mutect2, varscan2
- HCAR3 | c.8G>A p.R3Q | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs768138411, COSV63676750; called by muse, mutect2, varscan2
- HNRNPR | c.808A>T p.T270S | Missense Mutation (SNP) | VAF 5/100 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.517); catalogued as COSV56423316; called by muse, mutect2
- HTR2C | c.443T>A p.I148K | Missense Mutation (SNP) | VAF 4/96 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52220079, COSV99347962; called by muse, mutect2
- MYOM1 | c.3520G>T p.D1174Y | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV55295102, COSV55297857; called by muse, mutect2, varscan2
- NEDD4 | c.3089C>G p.S1030C (on ENST00000508342 / NM_001284338.1; = p.S611C on NM_006154.4) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100163568, COSV59064850; called by muse, mutect2, varscan2
- NSA2 | c.586A>C p.I196L | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV57188674; called by muse, varscan2
- OR56A3 | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.66); PolyPhen benign (0.021); catalogued as COSV61569771; called by muse, mutect2
- PDE4B | c.1651G>A p.D551N | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs749156051, COSV58470097; called by muse, mutect2, varscan2
- PIP5K1B | c.1547C>T p.T516I | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs377446511; called by muse, mutect2, varscan2
- POLM | c.686G>C p.R229P | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.854); catalogued as COSV54242691, COSV54243514; called by muse, mutect2, varscan2
- RHBDL2 | c.616C>T p.Q206* | Nonsense Mutation (SNP) | VAF 4/44 reads (9%) | catalogued as COSV56709194; called by muse, mutect2
- SLK | c.2789T>C p.I930T | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.44); PolyPhen benign (0.084); catalogued as COSV59827822; called by muse, mutect2, varscan2
- TDRD3 | c.1667G>T p.W556L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); catalogued as COSV52161257; called by muse, mutect2, varscan2
- TEX26 | c.483G>C p.K161N | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as COSV66839734, COSV66840420; called by muse, mutect2, varscan2
- TRMT10B | c.172A>G p.T58A | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53050950; called by muse, mutect2, varscan2
- ZBTB33 | c.832C>A p.P278T | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.056); catalogued as COSV58534699; called by muse, mutect2, varscan2
- ZNF41 | c.1523C>G p.T508R | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as COSV57444529; called by muse, mutect2, varscan2
- ZNF440 | c.229G>T p.D77Y | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.702); catalogued as COSV58371933; called by muse, mutect2, varscan2
- ZNF774 | c.341G>T p.G114V | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.027); catalogued as COSV62980658; called by muse, mutect2, varscan2
- FRG2C | c.158A>G p.E53G | Missense Mutation (SNP) | VAF 47/317 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2
- GTF3C6 | c.504del p.Q169Kfs*2 | Frame Shift Del (DEL) | VAF 17/62 reads (27%) | called by mutect2, pindel, varscan2
- IGHV3OR16-8 | c.107C>G p.S36C | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- CDC14A | c.1641G>A p.L547= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as COSV60561532; called by muse, mutect2, varscan2
- CELSR2 | c.7917C>T p.T2639= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as COSV54777082; called by muse, mutect2, varscan2
- DOCK9 | c.834C>T p.I278= (on ENST00000376460 / NM_001366676.2; = p.I279= on NM_015296.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/100 reads (17%) | catalogued as COSV59632466; called by muse, mutect2, varscan2
- ELAPOR1 | c.1533C>G p.L511= | Silent (SNP) | VAF 49/107 reads (46%) | catalogued as COSV64040917; called by muse, mutect2, varscan2
- EYA1 | c.1008C>T p.F336= | Silent (SNP) | VAF 33/83 reads (40%) | catalogued as COSV58169663; called by muse, mutect2, varscan2
- FA2H | c.1011C>T p.V337= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as rs746779418, COSV54727376; called by muse, mutect2, varscan2
- FKBP15 | c.282C>A p.G94= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as rs941495076, COSV53037889; called by muse, mutect2
- OR7D4 | c.249G>C p.V83= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as COSV58072157; called by muse, mutect2, varscan2
- PTOV1 | c.1164C>T p.N388= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs375764009; called by muse, mutect2, varscan2
- RGR | c.99C>G p.L33= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as COSV63894861; called by muse, mutect2, varscan2
- RTL9 | c.3543C>T p.D1181= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as rs138175129, COSV71826051; called by muse, mutect2, varscan2
- RTN4RL1 | c.435T>C p.F145= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as rs369962422; called by muse, mutect2, varscan2
- SAPCD2 | c.759C>T p.R253= | Silent (SNP) | VAF 3/10 reads (30%) | catalogued as rs1390505145, COSV68836760; called by muse, mutect2
- TMEM199 | c.252A>G p.E84= | Silent (SNP) | VAF 6/90 reads (7%) | catalogued as COSV50228737; called by muse, mutect2
- TRAK2 | c.408C>T p.L136= | Silent (SNP) | VAF 20/90 reads (22%) | catalogued as COSV100216994, COSV60273943; called by muse, mutect2
- ZNF746 | c.618G>A p.A206= | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as rs375984490; called by muse, mutect2, varscan2
